Somatic mutation profile of tumor specimen MP2PRT-PAPBTZ-TMP1-A (aliquot MP2PRT-PAPBTZ-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPBTZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (1,998 days).
Specimen MP2PRT-PAPBTZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d02e724-1c24-42c1-a5be-133616b576dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBTZ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBTZ-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f89f112-7079-468e-9895-bc60477d9ad8

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 8 silent.
By variant classification: Silent 8, Missense Mutation 7, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TIGD3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as rs776610460; called by muse, mutect2, varscan2
- TSPEAR | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 91/373 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782352724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WFIKKN2 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 383/635 reads (60%) | SIFT tolerated (0.69); PolyPhen benign (0.028); catalogued as rs370541134; called by muse, mutect2, varscan2
- CHRNB2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 139/376 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND2A | c.976A>G p.K326E | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KDM4A | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 75/207 reads (36%) | called by muse, mutect2, varscan2
- PAX5 | c.410+1_410+2insCACGGG p.X137_splice | Splice Site (INS) | VAF 97/245 reads (40%) | called by mutect2, pindel, varscan2
- SH3TC2 | c.2945C>A p.T982N | Missense Mutation (SNP) | VAF 167/399 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ADGRB2 | c.1848G>A p.S616= | Silent (SNP) | VAF 197/484 reads (41%) | catalogued as rs1347257101; called by muse, mutect2, varscan2
- CCDC50 | c.510C>T p.L170= | Silent (SNP) | VAF 86/243 reads (35%) | called by muse, mutect2, varscan2
- COBLL1 | c.2397A>G p.R799= (on ENST00000392717; = p.R761= on NM_014900.5) | Silent (SNP) | VAF 69/222 reads (31%) | called by muse, mutect2, varscan2
- FAM184B | c.318C>T p.S106= | Silent (SNP) | VAF 176/440 reads (40%) | catalogued as rs1239411300; called by muse, mutect2
- GRAMD1B | c.855C>T p.S285= | Silent (SNP) | VAF 175/430 reads (41%) | catalogued as rs570692831; called by muse, mutect2, varscan2
- PCDHGA5 | c.72C>T p.C24= | Silent (SNP) | VAF 148/404 reads (37%) | catalogued as rs1156390539, COSV53962296, COSV99529675; called by muse, mutect2, varscan2
- RAPGEF3 | c.2169T>C p.C723= (on ENST00000389212; = p.C681= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 199/517 reads (38%) | called by muse, mutect2, varscan2
- UHMK1 | c.60G>A p.G20= | Silent (SNP) | VAF 188/489 reads (38%) | called by muse, mutect2, varscan2
